Gene-level copy-number profile of tumor specimen TCGA-TS-A7P6-01A from TCGA case TCGA-TS-A7P6, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 61.2 years (22,338 days).
Specimen TCGA-TS-A7P6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-MESO.15235122-261a-4937-9390-4c9a6ba7d336.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-TS-A7P6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ccc81df1-44e9-4a90-b7eb-839bb860ad90

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 17,042; copy number 2: 41,850; copy number 3: 903.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-TS-A7P6-01A-21D-A34B-01): tumor purity 0.66, ploidy 1.66, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:114,713,579–115,143,303, 4 genes: CIR1P2, RN7SL808P, NDST4, MRPS33P3.
- chr9:19,789,179–19,967,994, 5 genes (within-gene range 0–1): AL158077.2, AL158077.1, AL591222.1, AL591222.2, AL591222.3.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–1): AL359922.1.
- chr9:21,929,457–21,995,301, 3 genes: ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr9:27,829,276–27,944,497, 2 genes: AL360014.1, AL353746.1.
- chr9:28,148,211–28,149,236, 1 gene: AL451124.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 14,621. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
